FM case AD8729 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum.
https://portal.gdc.cancer.gov/cases/f4ae59fa-68be-4006-97cc-698d309c1fc3

Male, 44.5 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the rectum; metastasis biopsied or resected from the anal canal. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
